Somatic mutation profile of tumor specimen MP2PRT-PAWBYR-TBP1-A (aliquot MP2PRT-PAWBYR-TBP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAWBYR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.3 years (5,941 days).
Specimen MP2PRT-PAWBYR-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b62e718c-d835-41f5-bd96-940d20ca484d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWBYR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWBYR-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af55a71b-c92a-49cc-9952-f8a23cbcbe60

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNB1 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs869312821, CM164914, COSV66099716; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AGO2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 24/686 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV99596340; called by muse, mutect2
- FNTB | c.874T>A p.C292S | Missense Mutation (SNP) | VAF 99/724 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV55764506; called by muse, mutect2, varscan2
- NRG3 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV100930362, COSV64557266; called by muse, mutect2, varscan2
- PREX2 | c.2476G>A p.D826N | Missense Mutation (SNP) | VAF 84/558 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.559); catalogued as rs755479314, COSV55768273, COSV55788475; called by muse, mutect2, varscan2
- PTPRT | c.2531C>T p.T844M | Missense Mutation (SNP) | VAF 100/566 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs368317330, COSV62013434; called by muse, mutect2, varscan2
- RCCD1 | c.70G>C p.G24R | Missense Mutation (SNP) | VAF 226/919 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs773646131, COSV67793911; called by muse, mutect2, varscan2
- BARX2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 191/1080 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- KRTAP10-3 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 38/1128 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- LONRF1 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- MYO7A | c.3175A>G p.T1059A | Missense Mutation (SNP) | VAF 66/619 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MYO7B | c.826T>C p.S276P | Missense Mutation (SNP) | VAF 77/297 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PWWP3A | c.1973A>G p.D658G (on ENST00000627377; = p.D657G on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/437 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C8orf86 | n.493T>C | RNA (SNP) | VAF 91/666 reads (14%) | called by muse, mutect2, varscan2
- NFATC1 | c.*355C>T | 3'UTR (SNP) | VAF 56/451 reads (12%) | catalogued as rs761314981; called by muse, mutect2, varscan2
